Somatic mutation profile of tumor specimen TCGA-EE-A29A-06A (aliquot TCGA-EE-A29A-06A-12D-A196-08) from TCGA case TCGA-EE-A29A, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.3 years (26,779 days).
Specimen TCGA-EE-A29A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71afd7ca-1d08-4439-b7f5-036793b00986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29A-10A (Blood Derived Normal), aliquot TCGA-EE-A29A-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/349ea59e-e1a9-4809-8d07-727ab0485fdd

The open-access MAF lists 315 somatic variants for this specimen: 200 protein-altering or splice-affecting, 109 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 109, Nonsense Mutation 10, Splice Site 3, Intron 2, Frame Shift Del 2, Frame Shift Ins 2, 3'Flank 2, 3'UTR 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL16 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs768772097, COSV61266597; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs767162674, COSV54026663; called by muse, mutect2, varscan2
- ABCG4 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV56642592; called by muse, mutect2, varscan2
- AC013489.1 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99183848; called by muse, mutect2, varscan2
- ACSS3 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768536849, COSV54087586, COSV99698395; called by muse, mutect2, varscan2
- ADAM10 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV53050194; called by muse, mutect2, varscan2
- ADAMTS6 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66857803; called by muse, mutect2, varscan2
- ADGRF3 | c.1877C>T p.S626F (on ENST00000311519 / NM_001145168.1; = p.S427F on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61049461; called by muse, mutect2, varscan2
- ADPRS | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs745628646, COSV52880546; called by muse, mutect2, varscan2
- ANK3 | c.3811G>A p.D1271N (on ENST00000280772 / NM_001320874.2; = p.D405N on NM_001149.3) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV55050009; called by muse, mutect2, varscan2
- APOL5 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV50766511; called by muse, mutect2, varscan2
- ARID1A | c.3598C>T p.Q1200* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV61375497; called by muse, mutect2, varscan2
- ASB4 | c.29A>T p.K10I | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs769481837, COSV57507612; called by muse, mutect2, varscan2
- ATP2A1 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs759217913, COSV62868877; called by muse, varscan2
- ATP8A1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52531360; called by muse, mutect2, varscan2
- BIN2 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as rs539014719, COSV57204534; called by muse, mutect2, varscan2
- BMP5 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63701719; called by muse, mutect2, varscan2
- C1QTNF9 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 79/138 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.132); catalogued as rs1256738551, COSV59656731; called by muse, mutect2, varscan2
- C7 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV100495599, COSV57472547; called by muse, mutect2, varscan2
- C8orf34 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV61375003, COSV61378967; called by muse, mutect2, varscan2
- CACNA1C | c.1506C>T p.F502= | Splice Region (SNP) | VAF 19/49 reads (39%) | catalogued as rs1186105533, COSV59705835, COSV59718866; called by muse, mutect2, varscan2
- CARD14 | c.2459G>C p.R820P | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV58338913; called by muse, mutect2, varscan2
- CDH22 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 77/118 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64836968, COSV64838570; called by muse, mutect2, varscan2
- CELA2A | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV62747306; called by muse, mutect2, varscan2
- CFI | c.1564A>T p.K522* | Nonsense Mutation (SNP) | VAF 81/200 reads (41%) | catalogued as COSV67098173; called by muse, mutect2, varscan2
- CHRNA7 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs754418919, COSV60967589; called by mutect2, varscan2
- CLEC14A | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 84/201 reads (42%) | catalogued as COSV60562110; called by muse, mutect2, varscan2
- CLSTN2 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV71719390; called by muse, mutect2, varscan2
- CLVS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV57971335; called by muse, mutect2, varscan2
- CNOT1 | c.1508T>G p.I503S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV57767368; called by muse, mutect2, varscan2
- CNTN5 | c.665A>C p.H222P | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV54294338; called by muse, mutect2
- CNTNAP4 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56671829; called by muse, mutect2, varscan2
- COL4A1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV65423209; called by muse, mutect2, varscan2
- COL7A1 | c.5756G>A p.G1919E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60393287; called by muse, mutect2, varscan2
- CORIN | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.205); catalogued as rs866164544, COSV56688788; called by muse, mutect2, varscan2
- CSMD1 | c.1183G>A p.E395K (on ENST00000520002; = p.E394K on NM_033225.6) | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV68183640, COSV68229493; called by muse, mutect2, varscan2
- CTNNB1 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs1306221365, COSV62694840; called by muse, mutect2, varscan2
- CTNND2 | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58862221, COSV58874910; called by muse, mutect2, varscan2
- DAB2 | c.1025A>T p.Y342F | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV57913261; called by muse, mutect2, varscan2
- DBI | c.34G>A p.E12K (on ENST00000355857 / NM_001079862.3; = p.E29K on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV58346037; called by muse, mutect2, varscan2
- DEFA3 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 58/382 reads (15%) | catalogued as COSV100590630; called by muse, varscan2
- DMC1 | c.698T>A p.F233Y | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV99319265; called by muse, mutect2, varscan2
- DNAH17 | c.10201C>T p.P3401S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745675410, COSV67751482; called by muse, mutect2, varscan2
- DOCK11 | c.2139G>A p.E713= | Splice Region (SNP) | VAF 37/44 reads (84%) | catalogued as COSV52235948; called by muse, mutect2, varscan2
- DYNC1H1 | c.7732G>A p.E2578K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs749628606, COSV64135334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELAPOR2 | c.1858C>T p.P620S (on ENST00000450689 / NM_001142749.3; = p.P453S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0.421); catalogued as COSV51885246; called by muse, mutect2, varscan2
- ELP4 | c.1120T>A p.L374I (on ENST00000350638; = p.L373I on NM_019040.5) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV63351242; called by muse, mutect2, varscan2
- ELSPBP1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1477014965, COSV60413242; called by muse, mutect2, varscan2
- EPG5 | c.7570C>T p.L2524F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56347118; called by muse, mutect2, varscan2
- EPS15 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV65541100; called by muse, mutect2, varscan2
- FAM181A | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50887968; called by muse, mutect2, varscan2
- FAT3 | c.8147C>T p.T2716I | Missense Mutation (SNP) | VAF 306/739 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV53091473, COSV53133065; called by muse, mutect2, varscan2
- FAT4 | c.12100G>A p.E4034K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1277850395, COSV58671125; called by muse, mutect2, varscan2
- FCHO1 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as COSV53181602; called by muse, mutect2, varscan2
- FLRT1 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); catalogued as COSV55361196; called by muse, mutect2, varscan2
- FOXR1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV57652000; called by muse, mutect2, varscan2
- FREM1 | c.5234G>T p.W1745L | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66520681; called by muse, mutect2, varscan2
- G2E3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV52839293; called by muse, mutect2, varscan2
- GABRG1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.689); catalogued as COSV54951561, COSV54962652; called by muse, mutect2, varscan2
- GAD2 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52153653; called by muse, mutect2, varscan2
- GALNTL5 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV67179634; called by muse, mutect2, varscan2
- GBF1 | c.1861C>T p.R621* (on ENST00000369983 / NM_001377137.1; = p.R620* on NM_004193.3) | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs766618538, COSV64143766; called by muse, mutect2, varscan2
- GIMAP6 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 76/544 reads (14%) | catalogued as COSV100188315, COSV61032894; called by muse, mutect2, varscan2
- GLG1 | c.2855G>A p.G952D | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV52665138; called by muse, mutect2, varscan2
- GLI1 | c.3092G>A p.G1031E | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV57359656; called by muse, mutect2, varscan2
- GRHL3 | c.1336C>T p.L446F (on ENST00000350501 / NM_198174.3; = p.L451F on NM_021180.3) | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.963); catalogued as COSV52565363; called by muse, mutect2, varscan2
- GRIN2A | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.482); catalogued as rs1200593226, COSV58026502, COSV58058380; called by muse, mutect2, varscan2
- GTPBP1 | c.1074-1G>A p.X358_splice | Splice Site (SNP) | VAF 69/191 reads (36%) | catalogued as COSV53283853; called by muse, mutect2, varscan2
- GTPBP4 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62550203; called by muse, mutect2, varscan2
- H2BW1 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as COSV54219890; called by muse, mutect2, varscan2
- HRC | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.433); catalogued as rs139799783, COSV99417593; called by muse, mutect2, varscan2
- HSD3B2 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV65592886, COSV65593923; called by muse, mutect2, varscan2
- HYDIN | c.11587C>T p.Q3863* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV66638063; called by muse, mutect2, varscan2
- IL12RB1 | c.125-1G>A p.X42_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as rs1486451138, COSV59096502; called by muse, mutect2, varscan2
- IL33 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV67342913; called by muse, mutect2, varscan2
- IMPG1 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100886337, COSV64055776; called by muse, mutect2, varscan2
- INTS5 | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.556); catalogued as COSV100399555; called by muse, mutect2, varscan2
- IQGAP2 | c.4231C>T p.R1411C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768773573, COSV57169603; called by muse, mutect2, varscan2
- ITGA4 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV51998900; called by muse, mutect2, varscan2
- JAKMIP2 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54600699, COSV54601846; called by muse, mutect2, varscan2
- KCNH8 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV60459333; called by muse, mutect2, varscan2
- KDM6B | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.735); catalogued as rs781392343, COSV54679567; called by muse, mutect2, varscan2
- KDR | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV55759061; called by muse, mutect2, varscan2
- KLHL1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.951); catalogued as COSV64769087; called by muse, mutect2, varscan2
- KLHL21 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66553165; called by muse, mutect2, varscan2
- LANCL2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as rs1173863905, COSV54648509; called by muse, mutect2, varscan2
- LDHB | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV63364472; called by muse, mutect2, varscan2
- LIFR | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV54686902; called by muse, mutect2, varscan2
- LMNA | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.326); catalogued as COSV61542262; called by muse, mutect2, varscan2
- LRIG3 | c.2017G>T p.V673L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs767613875, COSV57861418, COSV57862012; called by muse, mutect2, varscan2
- LRRC4C | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV53421396; called by muse, mutect2, varscan2
- MAP6 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV59074906; called by muse, mutect2, varscan2
- MARK3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.168); catalogued as COSV53508489, COSV53509001; called by muse, mutect2, varscan2
- MFSD9 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs373830901, COSV51495336; called by muse, mutect2, varscan2
- MFSD9 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs1388889758, COSV99302043; called by muse, mutect2, varscan2
- MGAT4B | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as rs749437560, COSV99482154; called by muse, mutect2, varscan2
- MLLT10 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as COSV56993311; called by muse, mutect2, varscan2
- MMP15 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV54678796; called by muse, mutect2, varscan2
- MPP6 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99757389; called by muse, mutect2, varscan2
- MPP6 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56039551, COSV99757390; called by muse, mutect2, varscan2
- MPP7 | c.1320T>A p.Y440* | Nonsense Mutation (SNP) | VAF 54/150 reads (36%) | catalogued as COSV61730998; called by muse, mutect2, varscan2
- MRPL40 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV54273513; called by muse, mutect2, varscan2
- MUC16 | c.16937C>T p.S5646F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.46); catalogued as rs759976473, COSV67454946; called by muse, mutect2, varscan2
- MUC16 | c.6941G>A p.G2314E | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs267605808, COSV67446356; called by muse, mutect2, varscan2
- MYH1 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56845725; called by muse, mutect2, varscan2
- MYO18B | c.7314A>C p.K2438N | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.572); catalogued as COSV59129490; called by muse, mutect2, varscan2
- NDST4 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52113218; called by muse, mutect2, varscan2
- NEDD4L | c.1324C>T p.R442C (on ENST00000400345 / NM_001144967.3; = p.R422C on NM_015277.6) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs762946023, COSV99894342; called by muse, mutect2, varscan2
- NOTCH2 | c.4187C>T p.P1396L | Missense Mutation (SNP) | VAF 123/347 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56697471; called by muse, mutect2, varscan2
- NOTCH2 | c.4186C>T p.P1396S | Missense Mutation (SNP) | VAF 122/344 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99863620; called by muse, mutect2, varscan2
- NOTCH3 | c.5465C>T p.S1822F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54630323; called by muse, mutect2, varscan2
- NPY1R | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV56713152; called by muse, mutect2, varscan2
- NPY5R | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV58451407; called by muse, mutect2, varscan2
- NRG2 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56831105, COSV99180205; called by muse, mutect2, varscan2
- NRG3 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV64551792, COSV64562656; called by muse, mutect2, varscan2
- OMP | c.458A>T p.N153I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV53686716; called by muse, mutect2, varscan2
- OR10J3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs867791135, COSV59953822; called by muse, mutect2, varscan2
- OR14J1 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV65845585; called by muse, mutect2, varscan2
- OR4K1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53459364; called by muse, mutect2, varscan2
- OR8D2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100659006, COSV62488292; called by muse, mutect2
- OVCH1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV58961101; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHAC1 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782385248, COSV53842849; called by muse, mutect2, varscan2
- PCDHB4 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as rs267600414, COSV52020950; called by muse, mutect2, varscan2
- PCDHB4 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV52020964; called by muse, mutect2, varscan2
- PDE8B | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 158/410 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV53734687; called by muse, mutect2, varscan2
- PEX12 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99862111; called by muse, mutect2, varscan2
- PGK2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV59163304; called by muse, mutect2, varscan2
- PITX1 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as COSV54761729; called by muse, mutect2
- PKDCC | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.12); catalogued as rs374316779, COSV54306252; called by muse, mutect2, varscan2
- PKHD1L1 | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV65740055; called by muse, mutect2, varscan2
- PKHD1L1 | c.3595G>A p.D1199N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV65740058; called by muse, mutect2, varscan2
- PMS2 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 141/217 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV56220587; called by muse, mutect2, varscan2
- POU6F2 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68870354, COSV68882556; called by muse, mutect2, varscan2
- PPM1E | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV57572133; called by muse, mutect2, varscan2
- PPP1R3A | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs868591967, COSV52876769; called by muse, mutect2, varscan2
- PRDM9 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV57003307; called by muse, mutect2, varscan2
- PRPF8 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV59260145, COSV59261900; called by muse, mutect2, varscan2
- PRRC2C | c.8375C>T p.P2792L (on ENST00000367742; = p.P2790L on NM_015172.4) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV58902906; called by muse, mutect2, varscan2
- PTPRH | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV54743916; called by muse, mutect2, varscan2
- PTPRK | c.3263G>A p.R1088Q (on ENST00000368215 / NM_001291984.2; = p.R1089Q on NM_002844.4) | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1302382517, COSV63893927; called by muse, mutect2, varscan2
- RFX6 | c.1183A>G p.I395V | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.248); catalogued as COSV60584113; called by muse, mutect2, varscan2
- RIN1 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60925946; called by muse, mutect2, varscan2
- RNF123 | c.3289C>T p.L1097F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1479436447, COSV100246522; called by muse, mutect2, varscan2
- RNF182 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV101337871; called by muse, mutect2, varscan2
- RNF31 | c.1843C>T p.Q615* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV53758868; called by muse, mutect2, varscan2
- SCN9A | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1367983811, COSV57604575; called by muse, mutect2, varscan2
- SEMA3A | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 83/122 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54865273; called by muse, mutect2, varscan2
- SEMA3G | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.621); catalogued as COSV51594557, COSV99203531; called by muse, mutect2, varscan2
- SLC14A1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1197896884, COSV58930784, COSV58931349; called by muse, mutect2, varscan2
- SLC15A4 | c.978G>C p.L326F | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV57160920, COSV99903325; called by muse, mutect2, varscan2
- SLC26A5 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59705197; called by muse, mutect2, varscan2
- SLC26A5 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs144150940; called by muse, mutect2, varscan2
- SLC35E2A | n.874+1G>A | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as rs1226103470, COSV55803127; called by mutect2, varscan2
- SLC38A4 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs1459034014, COSV56965953; called by muse, mutect2, varscan2
- SLC6A5 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV54223013; called by muse, mutect2, varscan2
- SLC8A2 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52638674; called by muse, mutect2, varscan2
- SLCO1B3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53934561; called by muse, mutect2, varscan2
- SMC1B | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs754324826, COSV100663134; called by muse, mutect2, varscan2
- SPHKAP | c.2489C>T p.S830F | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV60872824; called by muse, mutect2, varscan2
- SSH1 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV58455419; called by muse, mutect2, varscan2
- ST6GAL2 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 83/148 reads (56%) | PolyPhen possibly damaging (0.67); catalogued as COSV62416217; called by muse, mutect2, varscan2
- STRAP | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV50308304; called by muse, mutect2, varscan2
- TAS2R41 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601368, COSV68765074; called by muse, mutect2, varscan2
- TELO2 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs553962493, COSV51977721; called by muse, mutect2, varscan2
- TENM4 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1164223025, COSV53617500; called by muse, mutect2, varscan2
- THSD7B | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.393); catalogued as rs781009319, COSV55649283; called by muse, mutect2, varscan2
- TIGD2 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as rs1296885303, COSV57647469; called by muse, mutect2, varscan2
- TKTL2 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54918042; called by muse, mutect2, varscan2
- TMEM151A | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV59173040; called by muse, mutect2, varscan2
- TNFRSF10A | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV55325184; called by muse, mutect2, varscan2
- TRANK1 | c.4468C>T p.P1490S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57145329; called by muse, mutect2, varscan2
- TRPC6 | c.2223G>C p.E741D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV60252268; called by muse, mutect2, varscan2
- TTN | c.17903G>C p.R5968T (on ENST00000591111; = p.R5041T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/133 reads (56%) | PolyPhen benign (0); catalogued as COSV59957038, COSV60462793; called by muse, mutect2, varscan2
- UGGT1 | c.3967C>T p.R1323W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs367781664; called by muse, mutect2, varscan2
- UGT2A1 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV54139576; called by muse, mutect2, varscan2
- UGT2B28 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV59431268; called by muse, mutect2, varscan2
- UGT3A2 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762711271, COSV56929291; called by muse, mutect2, varscan2
- USP10 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs1224318040, COSV54747893; called by muse, mutect2, varscan2
- USP45 | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV59679587; called by muse, mutect2, varscan2
- VSTM4 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1027555232, COSV53677328; called by muse, mutect2, varscan2
- WFIKKN2 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV60958269; called by muse, mutect2, varscan2
- WRN | c.2234A>G p.N745S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV53297899; called by muse, mutect2, varscan2
- WRNIP1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs375911501; called by muse, mutect2, varscan2
- WWC3 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs773127503, COSV66502186; called by muse, mutect2, varscan2
- ZMIZ1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.981); catalogued as COSV57892389; called by muse, mutect2, varscan2
- ZNF160 | c.1759C>T p.H587Y | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61999232; called by muse, mutect2, varscan2
- ZNF212 | c.446G>C p.C149S | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.751); catalogued as COSV60024765; called by muse, mutect2
- ZNF219 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV53879048; called by muse, mutect2
- ZNF48 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.231); catalogued as COSV60782665; called by muse, mutect2, varscan2
- ZNF777 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 61/384 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.063); catalogued as COSV99925093; called by muse, mutect2, varscan2
- ERCC6L2 | c.4283C>T p.P1428L | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FAF1 | c.1529_1530del p.E510Afs*3 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by pindel, varscan2
- MUC2 | c.2816T>A p.I939N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PLPPR4 | c.970_971dup p.L324Ffs*25 | Frame Shift Ins (INS) | VAF 48/135 reads (36%) | called by mutect2, pindel, varscan2
- SLC20A1 | c.1005dup p.V336Rfs*11 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- TPTE | c.1090G>A p.E364K (on ENST00000618007 / NM_199261.4; = p.E346K on NM_199259.4) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2
- TUT4 | c.1158del p.I387* | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- ADGRF4 | c.1449C>T p.F483= | Silent (SNP) | VAF 75/281 reads (27%) | catalogued as COSV51950641, COSV51957029; called by muse, mutect2, varscan2
- AL031681.2 | c.3111G>A p.G1037= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1319061208, COSV100916969; called by muse, mutect2, varscan2
- AMER3 | c.258C>T p.F86= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV58465832; called by muse, mutect2
- ARHGAP30 | c.861G>A p.R287= | Silent (SNP) | VAF 76/193 reads (39%) | catalogued as rs140126629; called by muse, mutect2, varscan2
- ARID1A | c.3597C>T p.F1199= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV61384026; called by muse, mutect2, varscan2
- BCL11A | c.1356G>A p.E452= (on ENST00000335712 / NM_001365609.1; = p.E486= on NM_018014.4) | Silent (SNP) | VAF 102/188 reads (54%) | catalogued as COSV59626778; called by muse, mutect2, varscan2
- CACNA1C | c.5376G>A p.E1792= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV59705871; called by muse, mutect2, varscan2
- CACNA1F | c.5916C>T p.A1972= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV54294609; called by muse, mutect2, varscan2
- CACNA1S | c.1701C>T p.F567= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV62938040; called by muse, mutect2, varscan2
- CAMK4 | c.255C>T p.I85= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs201866448, COSV56662707; called by muse, mutect2, varscan2
- CER1 | c.345G>A p.P115= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as rs138557355; called by muse, mutect2, varscan2
- CNTLN | c.66C>T p.S22= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs747814189, COSV52071724; called by muse, mutect2, varscan2
- CRIP3 | c.69G>A p.K23= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV51483332, COSV51483391; called by muse, varscan2
- CTNNA3 | c.987C>T p.I329= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs372427902; called by muse, mutect2, varscan2
- DCDC1 | c.5172G>A p.E1724= (on ENST00000597505 / NM_001367979.1; = p.E831= on NM_020869.3) | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV57998242; called by muse, mutect2, varscan2
- DMC1 | c.699C>T p.F233= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV99319264; called by muse, mutect2, varscan2
- DSCAM | c.3099C>T p.F1033= | Silent (SNP) | VAF 60/101 reads (59%) | catalogued as COSV68023579; called by muse, varscan2
- EXOC3L1 | c.90G>A p.R30= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100103768; called by muse, mutect2, varscan2
- EXTL3 | c.1197C>T p.T399= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV55037355; called by muse, mutect2, varscan2
- FLRT1 | c.1020G>A p.R340= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99735016; called by muse, mutect2, varscan2
- FOXR1 | c.369C>T p.S123= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100392869; called by muse, mutect2, varscan2
- FPR2 | c.141G>A p.V47= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs775649566, COSV60672347; called by muse, mutect2, varscan2
- FSHR | c.918G>A p.Q306= | Silent (SNP) | VAF 53/198 reads (27%) | catalogued as COSV58620304; called by muse, mutect2, varscan2
- GGT5 | c.1029G>A p.P343= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs58692741, COSV54069287; called by muse, mutect2, varscan2
- GJA8 | c.822C>T p.I274= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs781834904, COSV53788326; called by muse, mutect2, varscan2
- GLRA2 | c.588G>A p.T196= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as rs113271440, COSV54338260, COSV54345780; called by muse, mutect2, varscan2
- GRHL2 | c.1242G>A p.K414= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV52546404; called by muse, mutect2, varscan2
- HK2 | c.1692G>A p.Q564= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV51874109; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.108C>T p.S36= | Silent (SNP) | VAF 59/171 reads (35%) | catalogued as rs763424964; called by muse, mutect2, varscan2
- IGHV6-1 | c.177C>T p.I59= | Silent (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.279C>T p.F93= | Silent (SNP) | VAF 55/380 reads (14%) | called by muse, mutect2, varscan2
- INTS5 | c.2232G>C p.G744= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100399552; called by muse, mutect2, varscan2
- JAZF1 | c.24C>T p.S8= | Silent (SNP) | VAF 342/513 reads (67%) | catalogued as COSV52234887; called by muse, mutect2, varscan2
- KCNA10 | c.504C>T p.F168= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV63904410; called by muse, mutect2, varscan2
- KIAA1328 | c.108A>G p.E36= | Silent (SNP) | VAF 58/98 reads (59%) | catalogued as COSV54450336; called by muse, mutect2, varscan2
- KIT | c.447G>A p.K149= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV55394219; called by muse, mutect2, varscan2
- KXD1 | c.516G>A p.E172= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs756968784, COSV55889226; called by muse, mutect2, varscan2
- MARCHF9 | c.657C>T p.L219= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV56984310; called by muse, mutect2, varscan2
- MFSD10 | c.939C>T p.F313= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1027207506, COSV53267335; called by muse, mutect2, varscan2
- MFSD9 | c.96G>A p.A32= | Silent (SNP) | VAF 40/61 reads (66%) | catalogued as rs1426887745, COSV99302046; called by muse, mutect2, varscan2
- MGAT4B | c.1308C>T p.I436= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs915196198, COSV99482156; called by muse, mutect2, varscan2
- MROH5 | c.708C>T p.F236= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs1187901405, COSV71300856; called by muse, mutect2, varscan2
- MRPL45 | c.795C>T p.I265= | Silent (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- MUC16 | c.23502G>A p.R7834= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV67454938; called by muse, mutect2, varscan2
- MUC17 | c.11565C>T p.F3855= | Silent (SNP) | VAF 108/157 reads (69%) | catalogued as COSV60283783; called by muse, mutect2, varscan2
- MUC3A | c.8706C>T p.I2902= | Silent (SNP) | VAF 175/421 reads (42%) | catalogued as rs1032433499, COSV60212948; called by muse, mutect2, varscan2
- MYH1 | c.345C>T p.I115= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as COSV55434490, COSV55441100; called by muse, mutect2, varscan2
- NEDD4L | c.1323C>T p.I441= (on ENST00000400345 / NM_001144967.3; = p.I421= on NM_015277.6) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV56845090; called by muse, mutect2, varscan2
- NFAM1 | c.600G>A p.R200= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs758434543, COSV100216012, COSV61194884; called by muse, mutect2, varscan2
- NIPBL | c.6831C>T p.S2277= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as rs1171333012, COSV56947049; called by muse, mutect2, varscan2
- NLRP9 | c.813C>T p.L271= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV60461202; called by muse, mutect2, varscan2
- NPHP4 | c.2358C>T p.V786= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs371647995; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPY2R | c.1008C>T p.F336= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV61527664; called by muse, mutect2, varscan2
- NUAK1 | c.1410G>A p.K470= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs751534999, COSV54601714; called by muse, mutect2, varscan2
- NUGGC | c.2355C>T p.S785= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV58433489; called by muse, varscan2
- OR4A15 | c.609G>A p.A203= | Silent (SNP) | VAF 51/101 reads (50%) | catalogued as rs141225150, COSV100123917; called by muse, mutect2, varscan2
- OR52L1 | c.525C>T p.I175= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV59986351; called by muse, mutect2, varscan2
- OR5L2 | c.186C>T p.F62= | Silent (SNP) | VAF 77/182 reads (42%) | catalogued as COSV65723514; called by muse, mutect2, varscan2
- OR6K3 | c.960C>T p.F320= (on ENST00000368146; = p.F304= on NM_001005327.2) | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs1247560700, COSV63745470, COSV63745584; called by muse, mutect2, varscan2
- P3H4 | c.744C>A p.A248= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV58635644; called by muse, mutect2, varscan2
- PCDHAC2 | c.1665G>A p.G555= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV53842858; called by muse, mutect2, varscan2
- PCDHGA3 | c.213G>A p.R71= | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as COSV53919276; called by muse, mutect2, varscan2
- PECR | c.855G>A p.G285= | Silent (SNP) | VAF 59/176 reads (34%) | catalogued as COSV54733882; called by muse, mutect2, varscan2
- PEX12 | c.57C>T p.S19= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV99862109; called by muse, mutect2, varscan2
- PHKA2 | c.1356G>A p.K452= | Silent (SNP) | VAF 27/34 reads (79%) | catalogued as rs992974011, COSV66053025; called by muse, mutect2, varscan2
- PPP1R18 | c.1006C>T p.L336= | Silent (SNP) | VAF 136/223 reads (61%) | catalogued as rs1481689388, COSV51295028; called by muse, mutect2, varscan2
- PPP2R5A | c.513G>A p.E171= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV54814967; called by muse, mutect2, varscan2
- PRMT7 | c.1665C>T p.F555= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV54711163; called by muse, mutect2
- PSG1 | c.55C>T p.L19= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as COSV54946626; called by muse, mutect2, varscan2
- RAB6C | c.21C>T p.F7= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs769043659, COSV101308484; called by muse, varscan2
- RB1CC1 | c.102C>T p.S34= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs1282271661, COSV50244817; called by muse, mutect2
- RBM47 | c.435C>T p.C145= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV55932211; called by muse, mutect2, varscan2
- RNF123 | c.3288C>T p.F1096= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs1004340746, COSV57538605; called by muse, mutect2, varscan2
- RNF182 | c.126G>A p.R42= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as COSV101337872; called by muse, mutect2, varscan2
- RRP1 | c.294C>T p.A98= | Silent (SNP) | VAF 55/197 reads (28%) | catalogued as COSV71856785; called by muse, mutect2, varscan2
- S1PR1 | c.780C>T p.I260= | Silent (SNP) | VAF 65/130 reads (50%) | catalogued as rs267597895, COSV59512780; called by muse, mutect2, varscan2
- SATB2 | c.975G>A p.R325= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV53480694; called by muse, mutect2, varscan2
- SEC14L4 | c.889C>T p.L297= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV55399016; called by muse, mutect2, varscan2
- SLC2A10 | c.234C>T p.I78= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV63714032; called by muse, mutect2, varscan2
- SLC6A4 | c.798C>T p.I266= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV55565864; called by muse, mutect2, varscan2
- SLC6A5 | c.2343C>T p.S781= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV54232990; called by muse, mutect2, varscan2
- SLC8A3 | c.1863G>A p.P621= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs376675749; called by muse, mutect2, varscan2
- SLITRK6 | c.231G>A p.T77= | Silent (SNP) | VAF 61/193 reads (32%) | catalogued as COSV68389727; called by muse, mutect2, varscan2
- SMC1B | c.804G>A p.K268= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs757823186, COSV100663135; called by muse, varscan2
- SNCAIP | c.2466G>A p.V822= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs747418990, COSV54405974; called by muse, mutect2, varscan2
- SORL1 | c.567C>T p.I189= | Silent (SNP) | VAF 72/290 reads (25%) | catalogued as COSV52751628; called by muse, mutect2, varscan2
- SPATA25 | c.525G>A p.E175= | Silent (SNP) | VAF 80/132 reads (61%) | catalogued as COSV51941333; called by muse, mutect2, varscan2
- STYXL2 | c.3258G>A p.R1086= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV54803621; called by muse, mutect2, varscan2
- SYN1 | c.507G>A p.R169= | Silent (SNP) | VAF 15/16 reads (94%) | catalogued as COSV55980433; called by muse, mutect2, varscan2
- SYT1 | c.282G>A p.K94= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV54039481; called by muse, mutect2, varscan2
- TACC3 | c.2157G>A p.E719= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV57603773; called by muse, mutect2, varscan2
- TELO2 | c.492C>T p.P164= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs780947006, COSV99248199; called by muse, mutect2, varscan2
- TMPRSS11B | c.1134C>T p.I378= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV60291725; called by muse, mutect2, varscan2
- TOM1L2 | c.282C>T p.F94= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV58884954; called by muse, mutect2, varscan2
- TRPC6 | c.525G>A p.R175= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs1039479012, COSV100723428, COSV60251046; called by muse, mutect2, varscan2
- TRPC6 | c.333C>T p.I111= | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as COSV60252279; called by muse, mutect2, varscan2
- TRPV2 | c.2241G>A p.E747= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs747176064, COSV58427825; called by muse, mutect2, varscan2
- TTC14 | c.795C>T p.F265= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV56010157; called by muse, mutect2, varscan2
- TTN | c.13833C>T p.L4611= (on ENST00000591111; = p.L3684= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/64 reads (61%) | catalogued as rs373875040, COSV59929491, COSV59957047; called by muse, mutect2, varscan2
- USP6 | c.2286C>T p.I762= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as COSV51478560; called by muse, mutect2, varscan2
- VPS13D | c.4206G>A p.L1402= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV50628913; called by muse, varscan2
- ZBBX | c.1662G>A p.L554= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV56785587; called by muse, mutect2, varscan2
- ZC3H7A | c.2631C>T p.S877= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV63268990; called by muse, mutect2, varscan2
- ZMYM1 | c.2593C>T p.L865= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV63251226; called by muse, mutect2, varscan2
- ZNF248 | c.549C>T p.I183= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs145831910, COSV61997382; called by muse, varscan2
- ZNF646 | c.351C>T p.L117= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV56212639; called by muse, mutect2, varscan2
- ZNF777 | c.357C>T p.S119= | Silent (SNP) | VAF 62/387 reads (16%) | catalogued as rs768598531, COSV99925095; called by muse, mutect2, varscan2
- ZNF827 | c.1350C>T p.L450= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV65225813; called by muse, mutect2, varscan2
- ZSCAN18 | c.1224C>T p.S408= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1331705528, COSV53731213; called by muse, mutect2, varscan2
- FMN1 | c.2044-2021G>A | Intron (SNP) | VAF 49/113 reads (43%) | catalogued as rs1555392789, COSV100567781, COSV57920122; called by muse, mutect2, varscan2
- IGHG1 | chr14:105737819 C>T | 3'Flank (SNP) | VAF 23/97 reads (24%) | catalogued as rs761915007; called by muse, mutect2, varscan2
- LIN54 | c.*1C>G | 3'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100464448; called by muse, mutect2
- MYL3 | chr3:46833088 G>A | 3'Flank (SNP) | VAF 31/80 reads (39%) | catalogued as rs199822832, COSV70133512; called by muse, mutect2, varscan2
- NXT1 | c.*2G>C | 3'UTR (SNP) | VAF 24/63 reads (38%) | catalogued as rs750903220, COSV99656329; called by muse, mutect2, varscan2
- RPS8 | c.518-126C>T | Intron (SNP) | VAF 72/181 reads (40%) | catalogued as COSV100785469; called by muse, mutect2, varscan2
